Gene-level copy-number profile of tumor specimen TCGA-OR-A5KO-01A from TCGA case TCGA-OR-A5KO, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 40.0 years (14,606 days).
Specimen TCGA-OR-A5KO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.154e9edd-b354-4e62-be0f-8b26ebddffbc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5KO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9394121f-e388-4a2b-922e-ee999df64d4e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 2: 1,051; copy number 3: 30,384; copy number 4: 51; copy number 5: 1,693; copy number 6: 25,738; copy number 7: 258; copy number 8: 48; copy number 9: 573; copy number 10: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5KO-01A-11D-A29H-01): tumor purity 0.96, ploidy 1.48, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–3): RB1.
- chr13:48,328,084–48,444,704, 4 genes: PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.
- chr14:45,502,742–45,569,069, 2 genes: AL162632.2, AL139354.1.
- chr22:28,883,572–29,057,488, 2 genes (within-gene range 0–3): ZNRF3, ZNRF3-IT1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 649 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–19,234,487, 353 genes, copy number 7–9 (broad region; genes not listed).
- chr6:109,390,215–109,691,217, 6 genes, copy number 8 (within-gene range 4–8): PPIL6, SMPD2, MICAL1, ZBTB24, AL109947.1, AK9.
- chr6:118,452,469–118,710,075, 6 genes, copy number 7 (within-gene range 3–7): AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10.
- chr6:120,015,179–120,015,257, 1 gene, copy number 10: MIR3144.
- chr6:136,545,192–136,552,554, 2 genes, copy number 10: RN7SKP299, AL024508.1.
- chr6:136,630,243–136,630,355, 1 gene, copy number 10: RNA5SP219.
- chr6:158,921,271–159,088,114, 5 genes, copy number 7 (within-gene range 3–7): AL627422.1, RNU6-293P, RSPH3, AL035530.2, TAGAP.
- chr10:2,724,819–4,891,975, 38 genes, copy number 9: AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2, LINC00702, LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P, MANCR, LINC00705, AC018978.1, AKR1E2, AKR1C6P.
- chr10:5,154,140–15,860,507, 195 genes, copy number 9 (broad region; genes not listed).
- chr16:87,696,485–88,856,970, 42 genes, copy number 8 (within-gene range 3–8): KLHDC4, AC010536.2, AC126696.3, AC126696.1, SLC7A5, MIR6775, AC126696.2, CA5A, AC133539.1, AC127455.1, BANP, AC134312.4, AC134312.3, AC134312.1, AC134312.2, AC134312.5, LINC02182, AC134312.6, AC138512.1, ZNF469, ZFPM1, MIR5189, AC116552.1, ZC3H18, IL17C, CYBA, MVD, SNAI3-AS1, SNAI3, RNF166, AC138028.3, CTU2, AC138028.6, PIEZO1, MIR4722, AC138028.4, AC138028.2, AC138028.5, AC138028.1, CDT1, APRT, GALNS.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
